Somatic mutation profile of tumor specimen TCGA-CR-7364-01A (aliquot TCGA-CR-7364-01A-11D-2012-08) from TCGA case TCGA-CR-7364, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 66.2 years (24,192 days).
Specimen TCGA-CR-7364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b147f786-b6a8-4686-87b0-f7740817f437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7364-10A (Blood Derived Normal), aliquot TCGA-CR-7364-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dec284a-479f-47f9-83e6-61b528a3b50d

The open-access MAF lists 508 somatic variants for this specimen: 382 protein-altering or splice-affecting, 112 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 332, Silent 112, Nonsense Mutation 25, Frame Shift Del 12, Splice Site 9, RNA 6, Intron 6, Frame Shift Ins 3, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PMS2 | c.537+1G>A p.X179_splice | Splice Site (SNP) | VAF 8/164 reads (5%) | catalogued as rs863224450, CS105418, COSV99764210; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.254del p.P85Lfs*38 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | catalogued as rs1064793279, COSV53087170; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.10927G>T p.A3643S | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV101446952; called by muse, mutect2, varscan2
- AC100868.1 | c.2044G>T p.G682W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV51845687, COSV99226063; called by muse, mutect2, varscan2
- ACE | c.2408C>A p.P803Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.864); catalogued as COSV52003657; called by muse, mutect2, varscan2
- ACTN2 | c.1719G>T p.Q573H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV100856798; called by muse, mutect2, varscan2
- ACTR6 | c.233T>A p.L78H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99498597; called by muse, mutect2, varscan2
- ADA | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100596117; called by muse, mutect2, varscan2
- ADAMTS16 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as COSV56999397, COSV99941133; called by muse, mutect2, varscan2
- ADAMTS16 | c.3307C>A p.L1103M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.523); catalogued as COSV99941136; called by muse, mutect2, varscan2
- ADGRF2 | c.1445A>G p.Y482C (on ENST00000296862 / NM_001368115.2; = p.Y414C on NM_153839.7) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752384382, COSV99731188; called by muse, mutect2, varscan2
- ADIPOR2 | c.1123A>G p.M375V | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1180207692, COSV100840101; called by muse, mutect2, varscan2
- ADORA2A | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100418010; called by muse, mutect2, varscan2
- AGAP6 | c.766G>A p.G256S (on ENST00000374056 / NM_001365867.1; = p.G279S on NM_001077665.2) | Missense Mutation (SNP) | VAF 127/494 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as rs782810440, COSV100929087, COSV65017324; called by muse, mutect2, varscan2
- AGO4 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100942932; called by muse, mutect2, varscan2
- AHNAK | c.4270G>C p.D1424H | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV99947400; called by muse, mutect2, varscan2
- AKAP11 | c.1837A>G p.S613G | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs944132242, COSV50300820; called by muse, mutect2, varscan2
- ALDH1B1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs61757680; called by muse, mutect2, varscan2
- ANKDD1A | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as rs750786354, COSV100731174; called by muse, mutect2, varscan2
- APOB | c.12097G>A p.D4033N | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.65); catalogued as COSV99262746, COSV99265587; called by muse, mutect2, varscan2
- ARFGAP2 | c.264+2T>A p.X88_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100096340; called by mutect2, varscan2
- ARHGEF1 | c.1658A>T p.Q553L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100528990; called by muse, mutect2, varscan2
- ASB8 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1484380597, COSV100402493; called by muse, mutect2, varscan2
- ASCC3 | c.5414A>T p.E1805V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100976458; called by muse, mutect2, varscan2
- ASCC3 | c.743G>C p.C248S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100225702; called by muse, mutect2, varscan2
- ASTN1 | c.2548G>T p.D850Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV99921585; called by muse, mutect2, varscan2
- ASZ1 | c.1374A>G p.I458M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV99498005; called by muse, mutect2, varscan2
- BACH2 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99999377; called by muse, mutect2, varscan2
- BCHE | c.32G>T p.R11I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100012516; called by muse, mutect2, varscan2
- BCORL1 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV54400781, COSV99498121; called by muse, mutect2, varscan2
- BMPER | c.1478T>G p.L493R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99779586; called by muse, mutect2, varscan2
- BSN | c.4762C>G p.Q1588E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99608410; called by muse, mutect2, varscan2
- C10orf53 | c.356T>A p.V119E | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV100935054; called by muse, mutect2, varscan2
- C1orf94 | c.1070G>T p.W357L (on ENST00000488417 / NM_001134734.2; = p.W167L on NM_032884.5) | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100974918; called by muse, mutect2, varscan2
- C8B | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100980768, COSV64778532; called by muse, mutect2, varscan2
- CAPSL | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV68439722; called by muse, mutect2, varscan2
- CCDC180 | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as rs1446070174, COSV100826691; called by muse, mutect2, varscan2
- CCDC34 | c.431C>G p.P144R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100156572, COSV58725227; called by muse, mutect2, varscan2
- CDH4 | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756374774, COSV100849794; called by muse, mutect2
- CDK5RAP2 | c.4702G>C p.D1568H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100575437; called by muse, mutect2, varscan2
- CEP85L | c.388A>T p.M130L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100821216; called by muse, mutect2
- CFAP43 | c.1568A>G p.Q523R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV99530735; called by muse, mutect2, varscan2
- CHAD | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99366179; called by muse, mutect2, varscan2
- CHAD | c.322C>A p.H108N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99366182; called by muse, mutect2, varscan2
- CHAT | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100340136; called by muse, mutect2, varscan2
- CHD7 | c.7883A>G p.H2628R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs777577551, COSV101418242; called by muse, mutect2, varscan2
- CIP2A | c.2650A>G p.M884V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.39); catalogued as COSV99842535, COSV99842886; called by muse, mutect2, varscan2
- CLC | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.06); catalogued as COSV55686906; called by muse, mutect2, varscan2
- CNGA1 | c.1492C>A p.P498T | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100652090, COSV100652218; called by muse, mutect2, varscan2
- CNOT6L | c.1105G>A p.D369N (on ENST00000504123 / NM_001286790.2; = p.D364N on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99361813; called by muse, mutect2, varscan2
- CNTN3 | c.2203G>C p.G735R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99724395; called by muse, mutect2, varscan2
- CNTNAP5 | c.2795C>A p.S932Y | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV70489662; called by muse, mutect2, varscan2
- COL2A1 | c.3956C>G p.T1319S | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100476407; called by muse, mutect2, varscan2
- COL2A1 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV100476414; called by muse, mutect2, varscan2
- COL6A3 | c.341del p.G114Efs*9 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as COSV55096379; called by mutect2, pindel, varscan2
- COL9A1 | c.1886A>T p.E629V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV100294799; called by muse, mutect2, varscan2
- COX7B2 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs775458548, COSV100260586; called by muse, mutect2, varscan2
- CPVL | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99605793; called by muse, mutect2, varscan2
- CRB1 | c.2568A>T p.R856S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100957869; called by muse, mutect2, varscan2
- CREB5 | c.1292T>A p.L431Q (on ENST00000357727 / NM_182898.4; = p.L424Q on NM_004904.3) | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100744640; called by muse, mutect2, varscan2
- CRISPLD1 | c.1244G>A p.R415K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51549059, COSV51552960; called by muse, mutect2, varscan2
- CRTAM | c.46+1G>A p.X16_splice | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99911994; called by muse, mutect2, varscan2
- CRYBG2 | c.4774C>T p.P1592S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV100366674; called by muse, mutect2, varscan2
- CRYGB | c.205T>C p.W69R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010008650, COSV99649952; called by muse, mutect2, varscan2
- CSAD | c.650G>A p.G217E (on ENST00000444623 / NM_001244705.2; = p.G244E on NM_015989.5) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914742; called by muse, mutect2, varscan2
- CSK | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV99583634; called by muse, mutect2, varscan2
- CSMD3 | c.10515C>G p.Y3505* (on ENST00000297405 / NM_001363185.1; = p.Y3336* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV52311916, COSV99834006, COSV99846545; called by muse, mutect2, varscan2
- CTNNA2 | c.982C>A p.R328S | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100783948, COSV63554502; called by muse, mutect2, varscan2
- CUBN | c.2021A>T p.Q674L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV100912650; called by muse, mutect2, varscan2
- CUX2 | c.205A>T p.K69* | Nonsense Mutation (SNP) | VAF 28/119 reads (24%) | catalogued as COSV99919633; called by muse, mutect2, varscan2
- CUX2 | c.2401G>T p.A801S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1160982706, COSV99919634; called by muse, mutect2, varscan2
- CYFIP2 | c.2765A>G p.Y922C (on ENST00000616178 / NM_001291722.2; = p.Y897C on NM_014376.4) | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1480245320, COSV100556853; called by muse, mutect2, varscan2
- CYP2D6 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV62244279; called by muse, mutect2, varscan2
- DACH1 | c.1793G>A p.G598E (on ENST00000619232 / NM_001366712.1; = p.G344E on NM_004392.6) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV57516906; called by muse, mutect2, varscan2
- DACH2 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV100913186; called by muse, mutect2
- DBR1 | c.1172A>T p.H391L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99604488; called by muse, mutect2, varscan2
- DCHS2 | n.1214G>C | Splice Region (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100251780; called by muse, mutect2, varscan2
- DCLK3 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs372300177, COSV69363914; called by muse, mutect2, varscan2
- DCTN1 | c.2218G>C p.E740Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV62620401; called by muse, mutect2, varscan2
- DCX | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100576434, COSV57571463; called by muse, mutect2, varscan2
- DHRS9 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59139109; called by muse, mutect2, varscan2
- DHX34 | c.3030G>T p.M1010I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100169570; called by muse, mutect2, varscan2
- DIAPH3 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs757557320, COSV99933511; called by muse, mutect2, varscan2
- DLGAP1 | c.837G>C p.W279C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV100230671; called by muse, mutect2, varscan2
- DNAH5 | c.10407G>T p.M3469I | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as COSV99449634; called by muse, mutect2, varscan2
- DNAH8 | c.8510C>A p.A2837D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100545191; called by muse, mutect2
- DSCAM | c.4531C>A p.L1511I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV101260099; called by muse, mutect2, varscan2
- DST | c.4268A>G p.D1423G (on ENST00000361203 / NM_001374722.1; = p.D1097G on NM_001723.6) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV99755732, COSV99756172; called by muse, mutect2, varscan2
- DTX4 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs767984984, COSV99915405; called by muse, varscan2
- DYRK4 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99156327; called by muse, mutect2, varscan2
- DYSF | c.3621G>T p.E1207D | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.859); catalogued as COSV99246972; called by muse, mutect2, varscan2
- EDRF1 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV100523469; called by muse, mutect2, varscan2
- ELP5 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV100598131; called by muse, mutect2, varscan2
- ENPP5 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100040456; called by muse, mutect2, varscan2
- EPG5 | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99957226; called by muse, mutect2, varscan2
- EPHB1 | c.2045G>T p.R682L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101213157, COSV67669185; called by muse, mutect2, varscan2
- ERICH3 | c.1285G>T p.G429W | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100444312; called by muse, mutect2, varscan2
- ERICH5 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100582773; called by muse, mutect2, varscan2
- ERN1 | c.2843T>C p.M948T | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs1567858832, COSV101458443; called by muse, mutect2, varscan2
- EVA1A | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV99285577; called by muse, mutect2, varscan2
- FAM47A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV60495968, COSV60498995; called by muse, mutect2, varscan2
- FAS | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 151/533 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100570817; called by muse, mutect2, varscan2
- FBLN5 | c.800G>C p.G267A | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99969583; called by muse, mutect2, varscan2
- FBXL18 | c.858G>C p.M286I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV101212064; called by muse, mutect2, varscan2
- FCRL4 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99619814; called by muse, mutect2, varscan2
- FGD3 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100490559; called by muse, mutect2, varscan2
- FGFRL1 | c.1373A>T p.H458L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.482); catalogued as COSV99294641; called by muse, mutect2
- FH | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV100845004, COSV100845021; called by muse, mutect2, varscan2
- FILIP1 | c.1772G>A p.C591Y | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.506); catalogued as COSV99384791; called by muse, mutect2, varscan2
- FMN2 | c.2894C>A p.P965H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV100145019; called by muse, mutect2, varscan2
- FNTB | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99862896; called by muse, mutect2, varscan2
- FOXC2 | c.1454C>A p.P485Q | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as COSV57444695; called by muse, mutect2, varscan2
- GABRA4 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51936721; called by muse, mutect2, varscan2
- GAGE12H | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as rs782776969, COSV101099149; called by muse, mutect2, varscan2
- GALNT13 | c.988G>T p.G330* | Nonsense Mutation (SNP) | VAF 56/197 reads (28%) | catalogued as COSV101222969; called by muse, mutect2, varscan2
- GANAB | c.2524G>A p.G842R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99641994, COSV99642196; called by muse, mutect2, varscan2
- GAPVD1 | c.2447C>T p.S816F (on ENST00000394104; = p.S843F on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as rs774179654, COSV99783172; called by muse, mutect2, varscan2
- GHDC | c.360C>G p.N120K | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1348448738, COSV100054697; called by muse, mutect2, varscan2
- GPR101 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV53239326; called by muse, mutect2, varscan2
- GPR63 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV100013339, COSV57742528; called by muse, mutect2, varscan2
- GPRASP1 | c.2442G>C p.W814C | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100850993, COSV100851019; called by muse, mutect2, varscan2
- GRIN2B | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV101663029; called by muse, mutect2, varscan2
- GUCY1A2 | c.1976G>T p.S659I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974651; called by muse, mutect2, varscan2
- H3C3 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100778292; called by muse, mutect2, varscan2
- HCN1 | c.1590G>C p.M530I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100300205; called by muse, mutect2, varscan2
- HEATR5A | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs191890003, COSV101119971; called by muse, mutect2, varscan2
- HFM1 | c.836C>A p.P279Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV99645502, COSV99645966; called by muse, mutect2, varscan2
- HGF | c.1353G>C p.W451C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99736929; called by muse, mutect2, varscan2
- HGS | c.1303A>G p.N435D | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100230493; called by muse, mutect2, varscan2
- HSPB3 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as rs755999042, COSV100115931, COSV57356875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUS1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370417384; called by muse, mutect2, varscan2
- IGF2BP3 | c.953T>A p.L318* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as COSV99325391; called by muse, mutect2, varscan2
- IGFL4 | c.195C>A p.S65R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100890845; called by muse, mutect2, varscan2
- IGKV2D-30 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.324); catalogued as rs752539702; called by muse, mutect2, varscan2
- IL17REL | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs147243670, COSV58008385; called by muse, mutect2, varscan2
- IL9R | c.659A>T p.H220L | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99729737; called by muse, varscan2
- INPP4B | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV53716655; called by muse, mutect2, varscan2
- ITIH4 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as rs748039841, COSV56572540, COSV99819357; called by muse, mutect2, varscan2
- IZUMO1R | c.450G>A p.W150* (on ENST00000440961; = p.W157* on NM_001199206.3) | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100126859; called by muse, mutect2, varscan2
- JAKMIP1 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99289576; called by muse, mutect2, varscan2
- JARID2 | c.1562C>G p.S521C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs866108564, COSV100521867, COSV59188817; called by muse, mutect2, varscan2
- KAT6A | c.950G>C p.R317P | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99705071; called by muse, mutect2, varscan2
- KCNA10 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370455162; called by muse, mutect2, varscan2
- KCNH5 | c.549+1G>T p.X183_splice | Splice Site (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100526553; called by muse, mutect2, varscan2
- KIAA0100 | c.1732G>A p.V578I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV101197309; called by muse, mutect2, varscan2
- KIAA1522 | c.2644C>G p.L882V (on ENST00000373480 / NM_001198972.2; = p.L941V on NM_020888.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99614592; called by muse, mutect2, varscan2
- KIF15 | c.4121G>A p.R1374H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs746764566, COSV58161186; called by muse, mutect2, varscan2
- KIF26A | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100181127; called by muse, mutect2, varscan2
- KIF26B | c.6247C>A p.R2083S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV100832379, COSV63652401; called by muse, mutect2, varscan2
- KLB | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.335); catalogued as COSV99962150; called by muse, mutect2, varscan2
- KLHDC7A | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101272772; called by muse, mutect2, varscan2
- KLHDC8A | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100903819; called by muse, mutect2, varscan2
- KLHL25 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs747115178, COSV100563576; called by muse, mutect2, varscan2
- KLHL4 | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV100909554; called by muse, mutect2, varscan2
- KMT5C | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99726185; called by muse, mutect2, varscan2
- KNDC1 | c.2576G>T p.S859I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV100464733; called by muse, varscan2
- KPNA2 | c.1238T>A p.I413N | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100388763; called by muse, mutect2, varscan2
- LAIR1 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100479636; called by muse, mutect2, varscan2
- LAMA2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101370441; called by muse, mutect2, varscan2
- LAMB4 | c.3524G>A p.C1175Y | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV52731399; called by muse, mutect2, varscan2
- LETM1 | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV100245446; called by muse, mutect2
- LGALS13 | c.92+1G>C p.X31_splice | Splice Site (SNP) | VAF 43/168 reads (26%) | catalogued as COSV99694933; called by muse, mutect2, varscan2
- LILRA1 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99251900; called by muse, mutect2, varscan2
- LILRA2 | c.952+1G>T p.X318_splice | Splice Site (SNP) | VAF 20/87 reads (23%) | catalogued as COSV99253362; called by muse, mutect2, varscan2
- LILRB1 | c.629C>G p.A210G (on ENST00000427581; = p.A174G on NM_006669.6) | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs772148886, COSV100207291; called by muse, varscan2
- LNX2 | c.214A>C p.K72Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV100310705; called by muse, mutect2, varscan2
- LONRF1 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV101238212; called by muse, mutect2, varscan2
- LRFN2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs760744849, COSV100599551; called by muse, mutect2, varscan2
- LRRC4C | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as COSV53419333, COSV53424717; called by muse, mutect2, varscan2
- LZTS3 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV100232266; called by muse, mutect2, varscan2
- MADD | c.2986G>T p.D996Y | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100211439; called by muse, mutect2, varscan2
- MAFB | c.765C>G p.C255W | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100965042; called by muse, mutect2, varscan2
- MAN2C1 | c.2990C>G p.A997G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV99145408, COSV99145879; called by muse, mutect2, varscan2
- MANEA | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100721525, COSV62590033; called by muse, mutect2, varscan2
- MAPKBP1 | c.2603C>T p.S868F (on ENST00000456763 / NM_001128608.2; = p.S862F on NM_014994.3) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99529407; called by muse, mutect2, varscan2
- MAPT | c.1165G>C p.E389Q (on ENST00000262410 / NM_001377265.1; = p.E314Q on NM_016835.4) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1463829855, COSV52247985, COSV52248769; called by muse, mutect2, varscan2
- MARCHF6 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as COSV99929639; called by muse, mutect2, varscan2
- MBD1 | c.207G>C p.L69F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV99496309; called by muse, mutect2, varscan2
- MC4R | c.440G>T p.R147M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55352692; called by muse, mutect2, varscan2
- MDH1B | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV65590220; called by muse, mutect2, varscan2
- MDN1 | c.13652C>G p.S4551* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV101021313; called by muse, mutect2, varscan2
- MED6 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV99832996; called by muse, mutect2, varscan2
- MERTK | c.1378A>G p.R460G | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV99774631; called by muse, mutect2, varscan2
- MIA3 | c.2990G>C p.R997P | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100719438, COSV60514254; called by muse, mutect2, varscan2
- MLLT1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV53129070; called by muse, mutect2, varscan2
- MUC16 | c.43067C>A p.A14356E | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.991); catalogued as COSV101109890, COSV101110050; called by muse, mutect2, varscan2
- MYCBP2 | c.8728G>T p.D2910Y (on ENST00000357337; = p.D2948Y on NM_015057.5) | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100630329; called by muse, mutect2, varscan2
- MYH4 | c.3418C>A p.R1140S | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769526708, COSV55122774, COSV99701250; called by muse, mutect2, varscan2
- MYO18B | c.6994G>T p.D2332Y | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.568); catalogued as COSV100123610; called by muse, mutect2, varscan2
- MYO1C | c.1255C>T p.L419F (on ENST00000648651 / NM_001080779.2; = p.L384F on NM_033375.5) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100704347; called by muse, mutect2, varscan2
- MYO1G | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745961199, COSV51854913; called by muse, mutect2, varscan2
- NAF1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs768892856, COSV99919103; called by muse, mutect2, varscan2
- NAV3 | c.2297G>C p.S766T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as COSV57077338, COSV57104056, COSV99890785; called by muse, mutect2, varscan2
- NCAPD2 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100217159; called by muse, mutect2, varscan2
- NCKAP5 | c.1980G>C p.R660S | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as COSV100491998; called by muse, mutect2, varscan2
- NCOR2 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100657318; called by muse, mutect2, varscan2
- NETO1 | c.221-2A>T p.X74_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100198708; called by muse, mutect2, varscan2
- NFXL1 | c.2474C>A p.T825K | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV101040325; called by muse, mutect2, varscan2
- NIPSNAP2 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 36/781 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100436724; called by muse, mutect2
- NMB | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV100850560; called by muse, mutect2, varscan2
- NOD2 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 32/73 reads (44%) | catalogued as rs147417132; called by muse, mutect2, varscan2
- NONO | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99338822; called by muse, mutect2, varscan2
- NOX3 | c.1624A>G p.R542G | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV99343128; called by muse, mutect2, varscan2
- NPAS3 | c.1766C>T p.A589V (on ENST00000356141 / NM_001164749.2; = p.A557V on NM_022123.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770665316, COSV100640213; called by mutect2, varscan2
- NRAP | c.2595G>T p.E865D (on ENST00000359988 / NM_001322945.2; = p.E830D on NM_006175.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100748425; called by muse, mutect2, varscan2
- NRN1 | c.242C>A p.T81K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs776418855, COSV99784165; called by muse, mutect2, varscan2
- NSD1 | c.5935G>T p.E1979* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as COSV100729031; called by muse, mutect2, varscan2
- NTRK3 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.821); catalogued as COSV100446523; called by muse, mutect2, varscan2
- NUBP1 | c.877A>T p.T293S | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.06); catalogued as COSV99296762; called by muse, mutect2, varscan2
- OGDHL | c.324C>A p.S108R | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100934313; called by muse, mutect2, varscan2
- OLAH | c.599T>A p.L200H (on ENST00000378228 / NM_001039702.3; = p.L253H on NM_018324.3) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100984747; called by muse, mutect2, varscan2
- OLIG3 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1393696814, COSV100880272; called by muse, mutect2, varscan2
- OR10A6 | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV100564283; called by muse, mutect2, varscan2
- OR10A7 | c.905A>G p.K302R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1248179422, COSV100406561; called by muse, mutect2
- OR10G2 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.921); catalogued as COSV101606941; called by muse, mutect2, varscan2
- OR2L8 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100594209, COSV100594353; called by muse, mutect2, varscan2
- OR2T8 | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV100178266; called by mutect2, varscan2
- OR51A2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as rs780732003, COSV100985060; called by muse, varscan2
- OR52A1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as rs764480143, COSV100200488; called by muse, mutect2, varscan2
- OR52H1 | c.661G>A p.A221T (on ENST00000322653; = p.A227T on NM_001005289.1) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs371667578; called by muse, mutect2
- OR5K4 | c.257T>A p.F86Y | Missense Mutation (SNP) | VAF 119/397 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100721347; called by muse, mutect2, varscan2
- OR5L1 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV100450055, COSV61735491; called by muse, mutect2, varscan2
- OR6Q1 | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100109944; called by muse, mutect2, varscan2
- OR8J1 | c.305del p.G102Efs*11 | Frame Shift Del (DEL) | VAF 32/125 reads (26%) | catalogued as COSV57319791; called by mutect2, pindel, varscan2
- OXSM | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); catalogued as rs760253551, COSV55000854, COSV99772001; called by muse, mutect2, varscan2
- PAH | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as CM961086, COSV100188048; called by muse, mutect2, varscan2
- PAMR1 | c.935C>G p.S312C (on ENST00000619888 / NM_001001991.3; = p.S329C on NM_015430.4) | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.552); catalogued as COSV99552587; called by muse, mutect2, varscan2
- PARD3B | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV100593411, COSV100594807; called by muse, mutect2, varscan2
- PCDHA6 | c.2234T>A p.V745E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); catalogued as COSV100971477; called by muse, mutect2, varscan2
- PCLAF | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV100256927; called by muse, mutect2, varscan2
- PCLO | c.2193G>T p.K731N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV100432475; called by muse, mutect2, varscan2
- PDE10A | c.1682T>C p.L561P | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100605069; called by muse, mutect2, varscan2
- PDE4DIP | c.5276C>T p.T1759I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV100519173; called by muse, mutect2, varscan2
- PDZRN4 | c.2413G>T p.E805* (on ENST00000402685 / NM_001164595.2; = p.E547* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as COSV100113685; called by muse, mutect2, varscan2
- PENK | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152312; called by muse, mutect2, varscan2
- PIEZO2 | c.6811C>G p.H2271D | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99554957; called by muse, mutect2, varscan2
- PIGA | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV61237541; called by muse, mutect2, varscan2
- PIK3R2 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99717410; called by muse, mutect2, varscan2
- PIKFYVE | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100010691; called by muse, mutect2, varscan2
- PIP4P2 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99575212; called by muse, mutect2, varscan2
- PKHD1L1 | c.11955G>T p.R3985S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV101006123; called by muse, mutect2, varscan2
- PLCXD1 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV101087867; called by muse, mutect2, varscan2
- PLG | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV99804643; called by muse, mutect2, varscan2
- PLXNA2 | c.3138C>G p.I1046M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV100885459, COSV65444249; called by muse, mutect2, varscan2
- PLXNC1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51573991; called by muse, mutect2, varscan2
- PLXNC1 | c.2531C>G p.P844R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99313090; called by muse, mutect2, varscan2
- PLXND1 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV100139707; called by muse, mutect2
- PM20D1 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as COSV100900187; called by muse, mutect2, varscan2
- POPDC3 | c.631T>A p.S211T | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99633711; called by muse, mutect2, varscan2
- PPBP | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1330178085, COSV56019493, COSV99933018; called by muse, mutect2, varscan2
- PPP1R17 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.244); catalogued as rs779073308, COSV100566375; called by muse, mutect2, varscan2
- PRELP | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557827; called by muse, mutect2, varscan2
- PRSS38 | c.890C>A p.T297N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100816480; called by muse, mutect2, varscan2
- PSG11 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100105801; called by muse, mutect2, varscan2
- PSME4 | c.3481T>A p.W1161R | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV101122488; called by muse, mutect2, varscan2
- PTCH2 | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100942104; called by muse, mutect2
- PTCHD3 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV101438906; called by muse, mutect2, varscan2
- PTPN22 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703627, COSV100703853; called by muse, mutect2, varscan2
- PTPRT | c.3289A>G p.I1097V | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100627224; called by muse, mutect2, varscan2
- PZP | c.160A>T p.N54Y | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99737778; called by muse, mutect2, varscan2
- RAD54L | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100914786, COSV64335867; called by muse, mutect2, varscan2
- RAVER2 | c.1750T>C p.Y584H (on ENST00000294428 / NM_001366165.1; = p.Y571H on NM_018211.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99605188; called by muse, mutect2, varscan2
- RCAN2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV100149709; called by muse, mutect2, varscan2
- REG3A | c.474G>T p.W158C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532556, COSV100532558; called by muse, mutect2, varscan2
- RELN | c.5821G>T p.V1941F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV100633701; called by muse, mutect2, varscan2
- RNF6 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100644630; called by muse, mutect2, varscan2
- ROS1 | c.1462C>A p.H488N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.3); catalogued as COSV100877057; called by muse, mutect2, varscan2
- RP1 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV99607454; called by muse, mutect2, varscan2
- RUNDC3A | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99841818; called by muse, mutect2, varscan2
- RYR2 | c.1211G>A p.S404N | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100770074; called by muse, mutect2, varscan2
- RYR2 | c.6224T>G p.I2075S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as CM147146, COSV100770075, COSV63710190; called by muse, mutect2, varscan2
- RYR3 | c.9443G>A p.G3148D (on ENST00000389232; = p.G3149D on NM_001036.6) | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101212745; called by muse, mutect2, varscan2
- SELE | c.1435G>T p.G479* | Nonsense Mutation (SNP) | VAF 33/139 reads (24%) | catalogued as COSV100324754, COSV60975631; called by muse, mutect2, varscan2
- SEMA3A | c.2086A>G p.T696A | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54881805; called by muse, mutect2, varscan2
- SEMA3B | c.2192G>A p.R731K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57113656; called by muse, mutect2
- SEMA5A | c.1888G>T p.G630W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101228502, COSV66790436; called by muse, mutect2, varscan2
- SEMA5A | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101228200; called by muse, mutect2, varscan2
- SFTPA1 | c.173-1G>T p.X58_splice | Splice Site (SNP) | VAF 107/400 reads (27%) | catalogued as COSV100957014; called by muse, mutect2, varscan2
- SGCB | c.430-2A>T p.X144_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV101197672; called by mutect2, varscan2
- SGTA | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV99682547; called by muse, mutect2, varscan2
- SGTA | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV99682548; called by muse, mutect2, varscan2
- SIK3 | c.593T>A p.I198K (on ENST00000445177 / NM_001366686.2; = p.I204K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99407987; called by muse, mutect2, varscan2
- SKIL | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99378255; called by muse, mutect2, varscan2
- SLC10A1 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99384343; called by muse, mutect2
- SLC10A2 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV99807946; called by muse, mutect2, varscan2
- SLC12A5 | c.3218T>A p.M1073K (on ENST00000454036 / NM_001134771.2; = p.M1050K on NM_020708.5) | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51642372, COSV99275572; called by muse, mutect2, varscan2
- SLC12A7 | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53762173, COSV99369856; called by muse, mutect2
- SLC24A5 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV99981634; called by muse, mutect2, varscan2
- SLC26A3 | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100384708, COSV60641277; called by muse, mutect2, varscan2
- SLC5A4 | c.52C>G p.P18A | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99831908; called by muse, mutect2, varscan2
- SLC6A7 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100046274; called by muse, mutect2, varscan2
- SLCO1C1 | c.1610T>C p.I537T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99859100; called by muse, mutect2, varscan2
- SLCO5A1 | c.1741T>G p.C581G | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99480004; called by muse, mutect2, varscan2
- SLIT2 | c.792G>C p.M264I | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99883761, COSV99887190; called by muse, mutect2, varscan2
- SLITRK1 | c.1973C>A p.A658E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.298); catalogued as COSV100999948; called by muse, mutect2, varscan2
- SLITRK4 | c.1924G>T p.V642F | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100567155; called by muse, mutect2, varscan2
- SMARCAL1 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100619883; called by muse, mutect2, varscan2
- SMC5 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.383); catalogued as COSV100747067, COSV63194661; called by muse, mutect2, varscan2
- SNX14 | c.1033G>A p.D345N (on ENST00000314673 / NM_001350535.1; = p.D301N on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100121545; called by muse, mutect2, varscan2
- SNX19 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as COSV56288337, COSV99773063; called by muse, mutect2
- SORL1 | c.5480G>T p.G1827V | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99493821; called by muse, mutect2, varscan2
- SPAG17 | c.1962G>C p.M654I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.49); catalogued as COSV100309069; called by muse, mutect2, varscan2
- SPATA21 | c.228G>C p.Q76H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as rs776982783, COSV100130913; called by muse, mutect2, varscan2
- SPG11 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV55993990, COSV99968632; called by muse, mutect2, varscan2
- SQOR | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99525773; called by muse, mutect2, varscan2
- SRRM4 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.003); catalogued as COSV99938498; called by muse, mutect2, varscan2
- ST8SIA3 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 15/50 reads (30%) | PolyPhen probably damaging (0.973); catalogued as COSV100129519; called by muse, mutect2, varscan2
- STXBP3 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV100893978; called by muse, mutect2, varscan2
- SUPV3L1 | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100669670; called by muse, mutect2, varscan2
- SYNE1 | c.15161G>T p.S5054I (on ENST00000367255 / NM_182961.4; = p.S4983I on NM_033071.3) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99563778; called by muse, mutect2, varscan2
- SYNE3 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV100515988; called by muse, mutect2, varscan2
- TARS3 | c.2021G>C p.G674A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100254625; called by muse, mutect2, varscan2
- TBL2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782398538, COSV99979615; called by muse, mutect2, varscan2
- TDRP | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100138508; called by muse, mutect2, varscan2
- TEAD4 | c.1010T>A p.F337Y | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100622032; called by muse, mutect2, varscan2
- TECPR1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101130481; called by muse, mutect2, varscan2
- THOC2 | c.993A>T p.E331D | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99833301; called by muse, mutect2, varscan2
- TIMM50 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as COSV100067918; called by muse, mutect2, varscan2
- TJP1 | c.4268A>T p.Q1423L | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV100632701; called by muse, mutect2, varscan2
- TMCC1 | c.1109G>T p.R370I (on ENST00000393238 / NM_001349268.2; = p.R46I on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100261025, COSV61440523; called by muse, mutect2, varscan2
- TMEM132B | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169659; called by muse, mutect2, varscan2
- TMEM200A | c.1036C>G p.P346A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as COSV51652887, COSV99759275; called by muse, mutect2, varscan2
- TMEM200C | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.142); catalogued as COSV101274834; called by muse, mutect2, varscan2
- TNIK | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99457211; called by muse, mutect2, varscan2
- TNRC6A | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs769506387, COSV100169990; called by muse, mutect2, varscan2
- TPR | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100823918; called by muse, mutect2, varscan2
- TPX2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1466152382, COSV100301714; called by muse, mutect2, varscan2
- TRPC1 | c.2154G>C p.K718N (on ENST00000476941 / NM_001251845.2; = p.K684N on NM_003304.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as COSV99858755; called by muse, mutect2, varscan2
- TTN | c.15734A>T p.Q5245L (on ENST00000591111; = p.Q4318L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/175 reads (32%) | PolyPhen benign (0.022); catalogued as COSV100611972; called by muse, mutect2, varscan2
- TTN | c.6950G>T p.R2317L (on ENST00000591111; = p.R2271L on NM_003319.4) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | PolyPhen probably damaging (0.998); catalogued as COSV100611973, COSV59964339; called by muse, mutect2, varscan2
- UGT2B17 | c.296A>T p.Y99F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV100497225; called by muse, mutect2, varscan2
- UGT3A1 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57102500, COSV99954725; called by muse, mutect2, varscan2
- UNC13C | c.6087A>G p.I2029M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99517055; called by muse, mutect2
- USH2A | c.9542G>A p.G3181E | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV56406512; called by muse, mutect2, varscan2
- USH2A | c.6570G>T p.W2190C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100234493; called by muse, mutect2, varscan2
- USP17L2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs367856582, COSV100414597; called by muse, mutect2, varscan2
- USP46 | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71512645, COSV99069985; called by muse, mutect2, varscan2
- USP9X | c.6412G>A p.A2138T | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100199224; called by muse, mutect2, varscan2
- VPS13C | c.926C>T p.P309L (on ENST00000644861 / NM_020821.3; = p.P266L on NM_017684.5) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99828453; called by muse, mutect2, varscan2
- VPS37B | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99458746; called by muse, mutect2, varscan2
- VSTM4 | c.234G>T p.M78I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.219); catalogued as COSV100039311; called by muse, varscan2
- VSTM4 | c.233T>A p.M78K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.874); catalogued as COSV100039314; called by muse, mutect2, varscan2
- WDR17 | c.2993A>T p.E998V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); catalogued as rs141454308; called by muse, mutect2, varscan2
- WDR25 | c.887G>C p.R296P | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100091781, COSV58936490, COSV58940543; called by muse, mutect2, varscan2
- WDR43 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1411224259, COSV101332957; called by muse, mutect2
- WLS | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs200839533, COSV52039363; called by muse, mutect2, varscan2
- XIRP1 | c.2781G>T p.Q927H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100453635; called by muse, mutect2, varscan2
- YY2 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 96/189 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63411031; called by muse, mutect2, varscan2
- ZFAT | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs1477809616, COSV100914560; called by muse, mutect2, varscan2
- ZFHX3 | c.2701G>C p.A901P | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99201248; called by muse, mutect2, varscan2
- ZMYM3 | c.3370C>T p.R1124W | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100077866; called by muse, mutect2, varscan2
- ZNF135 | c.1048G>A p.G350R (on ENST00000313434 / NM_001289401.2; = p.G362R on NM_003436.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272471702, COSV100536605; called by muse, mutect2, varscan2
- ZNF253 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs780238274, COSV100849515; called by muse, mutect2, varscan2
- ZNF282 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 75/258 reads (29%) | catalogued as COSV100021664; called by muse, mutect2, varscan2
- ZNF285 | c.1420C>A p.H474N | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100449990; called by muse, mutect2, varscan2
- ZNF350 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs777940934, COSV54709929; called by muse, mutect2, varscan2
- ZNF350 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.832); catalogued as COSV99702530; called by muse, mutect2, varscan2
- ZNF407 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV99995681; called by muse, varscan2
- ZNF48 | c.94A>T p.N32Y | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV100198124; called by muse, mutect2, varscan2
- ZNF513 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV99277599; called by muse, mutect2, varscan2
- ZNF560 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV56867484; called by muse, mutect2, varscan2
- ZNF621 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100182690; called by muse, mutect2, varscan2
- ZNF835 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV101606340; called by muse, mutect2, varscan2
- ZNF99 | c.2366A>T p.Y789F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV101233825; called by muse, mutect2, varscan2
- ZNF99 | c.2199C>A p.Y733* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV68056148; called by muse, mutect2, varscan2
- CD163 | c.2412dup p.Q805Afs*25 | Frame Shift Ins (INS) | VAF 49/259 reads (19%) | called by mutect2, pindel, varscan2
- CREB1 | c.65del p.N22Tfs*4 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- GRIP2 | c.1751T>G p.V584G (on ENST00000619221; = p.V487G on NM_001080423.4) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HNRNPA2B1 | c.986dup p.P330Tfs*37 (on ENST00000354667 / NM_031243.3; = p.P318Tfs*37 on NM_002137.4) | Frame Shift Ins (INS) | VAF 23/120 reads (19%) | called by mutect2, pindel, varscan2
- IGHG3 | c.416C>G p.P139R | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT tolerated (0.55); called by muse, varscan2
- IGHM | c.1249del p.H417Mfs*21 | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | called by mutect2, pindel, varscan2
- IGKV1-16 | c.53del p.P18Qfs*9 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | called by mutect2, varscan2
- IGKV1-6 | c.213T>A p.Y71* | Nonsense Mutation (SNP) | VAF 89/318 reads (28%) | called by muse, mutect2, varscan2
- IGKV3D-15 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- IL1RAPL2 | c.250del p.E84Kfs*11 | Frame Shift Del (DEL) | VAF 24/55 reads (44%) | called by mutect2, pindel, varscan2
- IL36G | c.281dup p.P95Afs*32 | Frame Shift Ins (INS) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- MTA1 | c.523del p.A175Qfs*7 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- PEG3 | c.1938del p.I648Sfs*90 | Frame Shift Del (DEL) | VAF 29/138 reads (21%) | called by mutect2, pindel, varscan2
- PTPRU | c.2218del p.Q740Rfs*47 | Frame Shift Del (DEL) | VAF 22/105 reads (21%) | called by mutect2, pindel, varscan2
- RBP3 | c.1585C>G p.P529A | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SELP | c.575del p.P192Qfs*6 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- TTN | c.92995del p.Q30999Kfs*3 (on ENST00000591111; = p.Q23575Kfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 60/273 reads (22%) | called by mutect2, pindel, varscan2
- ACSM5 | c.432G>T p.P144= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100088901, COSV59371507; called by muse, mutect2, varscan2
- ADAM29 | c.93G>T p.P31= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV100822012; called by muse, mutect2, varscan2
- ADCY2 | c.564C>A p.V188= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV57878609; called by muse, mutect2, varscan2
- AK5 | c.693G>A p.E231= (on ENST00000354567 / NM_174858.3; = p.E205= on NM_012093.4) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100481472; called by muse, mutect2, varscan2
- AP3B2 | c.3163C>T p.L1055= (on ENST00000261722; = p.L1049= on NM_004644.5) | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV55609309, COSV99916216; called by muse, mutect2, varscan2
- AP3B2 | c.3162C>A p.T1054= (on ENST00000261722; = p.T1048= on NM_004644.5) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99916482; called by muse, mutect2, varscan2
- ARHGAP24 | c.975T>C p.H325= (on ENST00000395184 / NM_001025616.3; = p.H232= on NM_031305.3) | Silent (SNP) | VAF 47/184 reads (26%) | catalogued as COSV99982064; called by muse, mutect2, varscan2
- ARIH2 | c.1479C>G p.T493= | Silent (SNP) | VAF 54/185 reads (29%) | catalogued as COSV100711314, COSV62705609; called by muse, mutect2, varscan2
- ASB15 | c.1584C>A p.R528= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs1287226303, COSV99306514, COSV99306607; called by muse, mutect2, varscan2
- ASPM | c.7434A>G p.Q2478= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV99660340; called by muse, mutect2, varscan2
- ATRNL1 | c.1458G>A p.G486= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100745442; called by muse, mutect2, varscan2
- CA2 | c.384G>T p.G128= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV99570054; called by muse, mutect2, varscan2
- CASKIN1 | c.1233C>A p.G411= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100624088; called by muse, mutect2, varscan2
- CATSPER3 | c.898C>A p.R300= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs142712287, COSV99254099; called by muse, mutect2, varscan2
- CCL2 | c.33G>T p.L11= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99861524; called by muse, mutect2, varscan2
- CCN2 | c.837C>T p.Y279= | Silent (SNP) | VAF 87/424 reads (21%) | catalogued as COSV100915315; called by muse, mutect2, varscan2
- CD101 | c.1683C>T p.S561= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV56719812; called by muse, mutect2, varscan2
- CD1D | c.378C>T p.N126= | Silent (SNP) | VAF 58/229 reads (25%) | catalogued as rs772184982, COSV63809575; called by muse, mutect2, varscan2
- CEACAM7 | c.471G>T p.P157= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as COSV104375073, COSV99137221; called by muse, mutect2, varscan2
- CHKB | c.834G>C p.G278= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV100376650; called by muse, mutect2, varscan2
- CLRN1 | c.291C>A p.I97= (on ENST00000327047 / NM_174878.3; = p.I21= on NM_052995.2) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99902477; called by muse, mutect2, varscan2
- CNKSR3 | c.1545C>T p.A515= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV101401361; called by muse, mutect2, varscan2
- COL11A2 | c.4494C>A p.G1498= (on ENST00000341947 / NM_080680.3; = p.G1391= on NM_080679.2) | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs576235181, COSV100553990, COSV59498722; called by muse, mutect2, varscan2
- CSF2 | c.117C>A p.A39= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99735699; called by muse, mutect2, varscan2
- CSMD3 | c.9606C>A p.G3202= (on ENST00000297405 / NM_001363185.1; = p.G3033= on NM_052900.3) | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV99834008; called by muse, mutect2, varscan2
- CSMD3 | c.8139C>T p.S2713= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52333017; called by muse, mutect2, varscan2
- CTNND1 | c.105C>G p.R35= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100650081; called by muse, mutect2, varscan2
- CUL4A | c.594G>A p.L198= (on ENST00000375440 / NM_001008895.4; = p.L98= on NM_003589.3) | Silent (SNP) | VAF 47/88 reads (53%) | catalogued as rs1274468369, COSV100417230; called by muse, mutect2, varscan2
- CYB5R3 | c.849C>G p.A283= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99349088; called by mutect2, varscan2
- DNAH1 | c.10714C>A p.R3572= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV101325743, COSV70227913; called by muse, mutect2, varscan2
- DNAH5 | c.8728C>T p.L2910= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99449636; called by muse, mutect2, varscan2
- DNAH7 | c.5599T>C p.L1867= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs149685696, COSV100414871; called by muse, mutect2, varscan2
- DOK5 | c.837A>G p.G279= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99373857; called by muse, mutect2, varscan2
- EED | c.819A>T p.A273= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV99646375; called by muse, mutect2, varscan2
- EGF | c.2274G>A p.K758= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV99490908; called by muse, mutect2, varscan2
- EPB41L3 | c.45G>A p.Q15= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs575037905, COSV100549121; called by muse, mutect2, varscan2
- ESS2 | c.1284C>A p.L428= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99350872; called by muse, mutect2, varscan2
- FAM24A | c.129T>A p.A43= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV100925082; called by muse, mutect2, varscan2
- FBN2 | c.855G>T p.G285= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99327380; called by muse, mutect2, varscan2
- FCGBP | c.12270G>T p.V4090= | Silent (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- FGFR1 | c.108C>T p.A36= | Silent (SNP) | VAF 84/103 reads (82%) | catalogued as rs781277645, COSV100248187; called by muse, mutect2, varscan2
- FMN2 | c.2781C>T p.P927= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as rs1163533476, COSV60417437, COSV60455856; called by muse, mutect2, varscan2
- FTCD | c.1488C>T p.F496= | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as rs1279073607, COSV99385037; called by muse, mutect2, varscan2
- GAL3ST1 | c.1062C>T p.A354= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs1451658576, COSV58892368; called by muse, mutect2, varscan2
- GHRH | c.72T>A p.P24= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99411149, COSV99411254; called by muse, mutect2, varscan2
- GPER1 | c.972C>T p.Y324= | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as rs1444127064, COSV99866953; called by muse, mutect2, varscan2
- H3C3 | c.381G>T p.L127= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV100778293; called by muse, mutect2, varscan2
- HAPLN3 | c.354C>T p.R118= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs746694797, COSV62084575; called by muse, mutect2
- IGDCC4 | c.3372C>A p.A1124= | Silent (SNP) | VAF 104/242 reads (43%) | catalogued as COSV100732867; called by muse, mutect2, varscan2
- ITGA4 | c.2346A>G p.V782= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV101223329; called by muse, mutect2
- KCNK7 | c.765C>G p.T255= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100442166; called by muse, mutect2, varscan2
- KMT5B | c.1383G>A p.L461= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100430199; called by muse, mutect2, varscan2
- KNDC1 | c.3900G>T p.T1300= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as rs756781058, COSV100464738; called by muse, mutect2, varscan2
- LAMA1 | c.8100G>A p.Q2700= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV101056336; called by muse, mutect2, varscan2
- LHX9 | c.931T>C p.L311= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100435878; called by muse, mutect2, varscan2
- LOXL4 | c.1935C>T p.D645= | Silent (SNP) | VAF 50/173 reads (29%) | catalogued as COSV99583866; called by muse, mutect2, varscan2
- MAGEA10 | c.93C>T p.P31= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as COSV99726713; called by muse, mutect2, varscan2
- MAML3 | c.3156C>T p.S1052= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV101558412; called by muse, mutect2, varscan2
- MED6 | c.531G>T p.V177= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99832997; called by muse, mutect2, varscan2
- MINPP1 | c.30G>T p.R10= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1415866380, COSV100916758; called by muse, mutect2, varscan2
- MUC16 | c.27777C>A p.P9259= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV101199900; called by muse, mutect2, varscan2
- MYZAP | c.1128A>G p.S376= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs983679332, COSV99984936; called by muse, mutect2, varscan2
- NCAM2 | c.1149A>C p.A383= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99522970; called by mutect2, varscan2
- NEURL2 | c.417A>G p.P139= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV99509856; called by muse, mutect2, varscan2
- NOMO1 | c.2868G>T p.G956= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99814532, COSV99814566; called by mutect2, varscan2
- NR5A1 | c.1113C>G p.L371= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV101007678, COSV101007686; called by muse, mutect2, varscan2
- NRG4 | c.195T>C p.F65= | Silent (SNP) | VAF 104/208 reads (50%) | catalogued as rs1467929194, COSV101204857; called by muse, mutect2, varscan2
- NTM | c.771G>A p.K257= | Silent (SNP) | VAF 58/206 reads (28%) | catalogued as COSV66172309; called by muse, mutect2, varscan2
- OR10G8 | c.288C>T p.C96= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as COSV101461835; called by muse, mutect2, varscan2
- OR51B5 | c.312A>T p.S104= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100332542; called by muse, mutect2, varscan2
- OR51I2 | c.192C>A p.S64= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV100413393, COSV100413508; called by muse, mutect2, varscan2
- OR8G2P | c.204C>T p.F68= | Silent (SNP) | VAF 50/184 reads (27%) | catalogued as rs1355098604; called by muse, mutect2, varscan2
- OTOF | c.3702A>C p.P1234= (on ENST00000272371 / NM_194248.3; = p.P487= on NM_004802.4) | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99717648; called by muse, mutect2, varscan2
- P3H3 | c.1041G>A p.P347= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as rs781817957, COSV51831062; called by muse, mutect2, varscan2
- PCLO | c.1107T>C p.A369= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100432479; called by muse, mutect2, varscan2
- PHACTR1 | c.348G>A p.L116= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100276908; called by muse, mutect2, varscan2
- PHF20L1 | c.2808A>G p.P936= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99621243; called by muse, mutect2, varscan2
- PKHD1L1 | c.10686T>C p.A3562= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs773331448, COSV101006122; called by muse, mutect2, varscan2
- PTCHD3 | c.1569G>T p.L523= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV101438905; called by muse, mutect2
- PTGFRN | c.585C>T p.S195= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV101277343; called by muse, mutect2, varscan2
- PTK2B | c.2562G>A p.G854= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV57756291; called by muse, mutect2, varscan2
- PTPRD | c.5232C>A p.T1744= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100644778; called by muse, mutect2, varscan2
- RELA | c.1515A>T p.T505= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100425827; called by muse, mutect2, varscan2
- RELN | c.5259G>A p.G1753= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV59000618, COSV59013077; called by muse, mutect2, varscan2
- REN | c.276C>T p.I92= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs373309460, COSV99689527; called by muse, mutect2, varscan2
- RNF150 | c.885C>A p.P295= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100153430; called by muse, mutect2, varscan2
- RYR2 | c.5841C>A p.V1947= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV63680548, COSV63692120; called by muse, mutect2, varscan2
- SEC61A1 | c.738C>T p.I246= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as COSV99684862; called by muse, mutect2, varscan2
- SERTAD4 | c.1041A>G p.K347= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100882612; called by muse, mutect2, varscan2
- SLC24A1 | c.120C>T p.H40= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV99978271; called by muse, mutect2, varscan2
- SLC36A2 | c.1278G>A p.L426= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100079119; called by muse, mutect2, varscan2
- SLF2 | c.1296G>A p.K432= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV99489169; called by muse, mutect2, varscan2
- SON | c.1674G>T p.L558= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV99278271; called by muse, mutect2, varscan2
- SPATA31D1 | c.1792C>T p.L598= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV100782770; called by muse, mutect2, varscan2
- SRRM4 | c.1432C>A p.R478= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV57425239, COSV99938499; called by muse, mutect2
- ST6GALNAC3 | c.519G>A p.L173= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100083176; called by muse, mutect2, varscan2
- STAT5B | c.1440C>T p.A480= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99510956; called by muse, mutect2, varscan2
- TBC1D1 | c.1563G>A p.L521= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV99791206; called by muse, mutect2, varscan2
- TCP11L1 | c.1425G>A p.E475= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as rs1208689265, COSV100178132; called by muse, mutect2, varscan2
- TENT5C | c.192C>T p.I64= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV101032960; called by muse, mutect2, varscan2
- TMC4 | c.1119C>T p.T373= (on ENST00000617472 / NM_001145303.3; = p.T367= on NM_144686.4) | Silent (SNP) | VAF 56/208 reads (27%) | catalogued as COSV99713862; called by muse, mutect2, varscan2
- TMEM131L | c.4431C>T p.A1477= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99547372; called by muse, mutect2, varscan2
- TRIM25 | c.426C>T p.D142= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100380988; called by muse, mutect2, varscan2
- TTC24 | c.1404A>G p.K468= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100964334; called by muse, mutect2, varscan2
- TTN | c.48781C>A p.R16261= (on ENST00000591111; = p.R8837= on NM_003319.4) | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV100611969, COSV60389034; called by muse, mutect2, varscan2
- UGT2A1 | c.63G>A p.G21= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV54146348, COSV99684280; called by muse, mutect2, varscan2
- USP24 | c.7182G>T p.G2394= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV99599692; called by muse, mutect2, varscan2
- WDR17 | c.1266T>C p.D422= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99707569; called by muse, mutect2, varscan2
- XPO1 | c.103T>C p.L35= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV101294210; called by muse, mutect2, varscan2
- ZIC1 | c.1251G>T p.P417= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs758948864, COSV99291894; called by muse, mutect2, varscan2
- ZNF207 | c.642A>T p.P214= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as COSV100340499; called by muse, mutect2, varscan2
- ZNF222 | c.225A>G p.Q75= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99496349; called by muse, mutect2, varscan2
- AC024940.1 | n.3810G>A | RNA (SNP) | VAF 5/22 reads (23%) | catalogued as rs373647649; called by muse, mutect2, varscan2
- AC244258.1 | n.993G>T | RNA (SNP) | VAF 43/158 reads (27%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846410 G>A | 5'Flank (SNP) | VAF 30/46 reads (65%) | called by muse, mutect2, varscan2
- ANK1 | c.5395-1211A>T | Intron (SNP) | VAF 17/67 reads (25%) | catalogued as COSV99225201; called by muse, mutect2, varscan2
- CA10 | c.61+22833G>C | Intron (SNP) | VAF 23/102 reads (23%) | catalogued as rs774887176, COSV99562912; called by muse, mutect2, varscan2
- CTBP2 | c.58+11934G>C | Intron (SNP) | VAF 39/120 reads (33%) | catalogued as COSV100456442; called by muse, mutect2, varscan2
- CTDSP2 | c.412-299G>A | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as COSV101142999; called by muse, mutect2, varscan2
- FOLH1B | n.817C>T | RNA (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- MIR125B1 | n.1dup | RNA (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- SH2D6 | n.560G>C | RNA (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100442531; called by muse, mutect2, varscan2
- SNORD115-2 | n.34G>A | RNA (SNP) | VAF 59/244 reads (24%) | called by muse, mutect2, varscan2
- TAFA5 | c.113-70041C>A | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- TTN | c.34264+798A>C | Intron (SNP) | VAF 4/8 reads (50%) | catalogued as rs865901089, COSV100611970; called by muse, mutect2, varscan2
- ZSCAN20 | c.*1G>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100792594; called by muse, mutect2, varscan2
